Somatic mutation profile of tumor specimen TCGA-DD-AACJ-01A (aliquot TCGA-DD-AACJ-01A-11D-A40R-10) from TCGA case TCGA-DD-AACJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 75.4 years (27,528 days).
Specimen TCGA-DD-AACJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 383302a0-afb4-4fbc-804d-11e97e5bd9b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACJ-10A (Blood Derived Normal), aliquot TCGA-DD-AACJ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d64b84a-06a8-4ee0-baa2-26966e8a6948

The open-access MAF lists 99 somatic variants for this specimen: 79 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 69, Silent 20, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs104893614, CM980375, COSV55627817; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 50/126 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3971C>A p.S1324Y (on ENST00000272895 / NM_173076.3; = p.S1006Y on NM_015657.3) | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.237); catalogued as COSV55955310, COSV99791062; called by muse, mutect2
- ABCC2 | c.2810A>G p.N937S | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV100966626; called by muse, mutect2, varscan2
- ACVR2B | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1186630570, COSV100754294; called by muse, mutect2, varscan2
- ADAMTS19 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 198/325 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV99179619; called by muse, mutect2, varscan2
- ADRA1D | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101063084; called by muse, mutect2, varscan2
- AHCTF1 | c.3719C>T p.S1240F (on ENST00000366508; = p.S1214F on NM_015446.5) | Missense Mutation (SNP) | VAF 38/507 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404095; called by muse, mutect2
- AMTN | c.495G>C p.Q165H | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100219811, COSV59488541; called by muse, varscan2
- ARFGEF2 | c.2533+1G>A p.X845_splice | Splice Site (SNP) | VAF 62/174 reads (36%) | catalogued as COSV100904371; called by muse, mutect2, varscan2
- ATM | c.2042C>G p.S681C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1060501585, COSV99590718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCR | c.2744T>C p.V915A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1328058055, COSV100006042, COSV59934713; called by muse, mutect2, varscan2
- C11orf16 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as rs1425269327, COSV100393803; called by muse, mutect2, varscan2
- C2CD2L | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV60884514; called by muse, mutect2, varscan2
- CFTR | c.2753T>A p.I918N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99137887; called by muse, mutect2, varscan2
- DLST | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs146211570; called by muse, mutect2, varscan2
- FAR2 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99479390; called by muse, mutect2, varscan2
- FAT1 | c.13396A>G p.R4466G | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs758477097, COSV101499481; called by muse, mutect2, varscan2
- GABRB3 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347499222, COSV54661500, COSV54683742; called by muse, mutect2, varscan2
- GOLGB1 | c.7439A>G p.Y2480C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1337529584, COSV100511242; called by muse, mutect2, varscan2
- GPR161 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.499); catalogued as COSV99606983; called by muse, mutect2, varscan2
- GPR63 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100013491; called by muse, mutect2, varscan2
- GRAMD1B | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV100454992; called by muse, mutect2, varscan2
- H2AZ1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99597551; called by muse, mutect2, varscan2
- HECTD1 | c.6491T>C p.L2164S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV101237439; called by muse, mutect2, varscan2
- HIRA | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99600687; called by muse, varscan2
- IGSF9B | c.2165C>A p.P722H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100318077; called by muse, varscan2
- IST1 | c.1083A>C p.E361D (on ENST00000535424 / NM_001270976.1; = p.K347T on NM_014761.4) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV100324787; called by muse, mutect2, varscan2
- KANSL1 | c.1588A>G p.I530V | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs1386788892, COSV99294732; called by muse, mutect2, varscan2
- KBTBD6 | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101068753, COSV101068827; called by muse, mutect2, varscan2
- KDM5B | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV99351040; called by muse, mutect2, varscan2
- KIF7 | c.4003A>T p.M1335L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99177358; called by muse, mutect2, varscan2
- KRBA2 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752848441, COSV100497705; called by muse, mutect2, varscan2
- KRT20 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99391500; called by muse, mutect2, varscan2
- KRTAP10-7 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV100170226; called by muse, mutect2, varscan2
- LONRF1 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 67/94 reads (71%) | catalogued as COSV101238247; called by muse, mutect2, varscan2
- LYST | c.4359A>G p.I1453M | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV101089959; called by muse, mutect2, varscan2
- MBD3L1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1335218374, COSV99978016; called by muse, mutect2, varscan2
- MFSD6 | c.1619A>C p.E540A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99855294; called by muse, mutect2, varscan2
- NIF3L1 | c.796A>C p.I266L (on ENST00000409020 / NM_001369444.1; = p.I239L on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100677552; called by muse, mutect2, varscan2
- NLRC4 | c.827T>A p.I276N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV100707465; called by muse, mutect2, varscan2
- NME1-NME2 | c.668T>C p.V223A (on ENST00000555572; = p.V198A on NM_001018136.3) | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.438); catalogued as COSV100899933; called by muse, varscan2
- OR2L8 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1269026294, COSV100594267; called by muse, mutect2, varscan2
- P2RY1 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.609); catalogued as rs768092598, COSV100521742; called by muse, mutect2
- PLEKHA8 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as COSV99321963; called by muse, mutect2, varscan2
- PRKAG3 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99292051; called by muse, mutect2, varscan2
- PSEN1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs996227958, COSV99997983; called by muse, mutect2, varscan2
- PTCHD3 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV101438938; called by muse, mutect2, varscan2
- RAD54L2 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV99621617; called by muse, mutect2, varscan2
- RADIL | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs760261239, COSV101271543; called by muse, mutect2, varscan2
- RANBP2 | c.4552C>T p.P1518S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1178166510, COSV99312750; called by muse, mutect2, varscan2
- RBBP6 | c.5231A>G p.H1744R | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100154769; called by muse, mutect2, varscan2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, mutect2, varscan2
- SCN7A | c.2527T>A p.S843T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV101313308; called by muse, mutect2, varscan2
- SHANK1 | c.3023C>A p.A1008D | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.278); catalogued as COSV99521657; called by muse, mutect2, varscan2
- SHQ1 | c.697A>G p.S233G | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1207403318, COSV100345135; called by muse, mutect2, varscan2
- SIX5 | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353471; called by muse, mutect2
- SNX20 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs751339391, COSV56058051; called by muse, mutect2, varscan2
- SPCS2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV99734488; called by muse, mutect2, varscan2
- SPEM2 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100081169; called by muse, mutect2, varscan2
- SREBF2 | c.1045A>G p.K349E | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100761499; called by muse, mutect2, varscan2
- ST8SIA4 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 37/130 reads (28%) | catalogued as COSV51508834; called by muse, mutect2, varscan2
- STX10 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as rs1472027519, COSV99460293; called by muse, mutect2, varscan2
- TEP1 | c.3803del p.A1268Vfs*4 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as COSV53001917; called by mutect2, pindel, varscan2
- TFB1M | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as COSV100905221; called by muse, mutect2, varscan2
- TRIB1 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.266); catalogued as COSV100322565; called by muse, mutect2, varscan2
- TRIP11 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV99970937; called by muse, mutect2, varscan2
- UBR2 | c.3463A>G p.M1155V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100867485; called by muse, mutect2, varscan2
- XPOT | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1425244853, COSV100225253, COSV100225673; called by muse, mutect2, varscan2
- ZNF100 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV99974183; called by muse, mutect2, varscan2
- ZNF251 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV99478697; called by muse, mutect2, varscan2
- ZNF284 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as rs1242391965, COSV101399039; called by muse, mutect2, varscan2
- ZNF585B | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100459563; called by muse, mutect2, varscan2
- ZNF808 | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100708095; called by muse, mutect2, varscan2
- FARSA | c.1004_1023del p.A335Efs*19 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | called by mutect2, pindel, varscan2
- IFI30 | c.28del p.L10Cfs*23 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- JAM3 | c.723del p.N241Kfs*18 | Frame Shift Del (DEL) | VAF 45/113 reads (40%) | called by mutect2, pindel, varscan2
- REST | c.1336dup p.T446Nfs*18 | Frame Shift Ins (INS) | VAF 75/196 reads (38%) | called by mutect2, pindel, varscan2
- USP2 | c.484_489del p.D162_P163del | In Frame Del (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- ACRV1 | c.585T>C p.Y195= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100223601; called by muse, mutect2, varscan2
- ANKMY2 | c.207A>T p.G69= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs775505829, COSV100187204; called by muse, mutect2, varscan2
- API5 | c.207C>T p.D69= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs1179452323, COSV101124560; called by muse, mutect2, varscan2
- ARF6 | c.273C>T p.A91= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs760817062, COSV100028465; called by muse, mutect2, varscan2
- BIRC6 | c.8530C>T p.L2844= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV101428499, COSV70197306; called by muse, mutect2, varscan2
- COL22A1 | c.9C>A p.G3= | Silent (SNP) | VAF 78/149 reads (52%) | catalogued as COSV100276638, COSV100279544; called by muse, mutect2, varscan2
- DTX3L | c.336G>A p.P112= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs764423884, COSV56144926; called by muse, mutect2, varscan2
- HPR | c.747C>T p.Y249= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs773674981, COSV57183683; called by muse, mutect2, varscan2
- IGFBPL1 | c.700C>A p.R234= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100890775; called by muse, mutect2, varscan2
- LAMA1 | c.4107G>T p.V1369= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs374423781, COSV67536817; called by muse, mutect2, varscan2
- MLIP | c.1233A>G p.P411= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as rs1313193595, COSV99229943; called by muse, mutect2, varscan2
- NTRK2 | c.2238T>A p.I746= (on ENST00000323115 / NM_001369534.1; = p.I762= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV99457040; called by muse, mutect2, varscan2
- NUP35 | c.555T>A p.S185= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99717899; called by muse, mutect2, varscan2
- OR6K2 | c.729C>T p.V243= | Silent (SNP) | VAF 40/320 reads (13%) | catalogued as rs1373077647, COSV62744134; called by muse, mutect2, varscan2
- OR6N1 | c.933G>A p.L311= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV58647249; called by muse, mutect2, varscan2
- PAPPA2 | c.5064C>T p.P1688= | Silent (SNP) | VAF 102/153 reads (67%) | catalogued as rs777455062, COSV100868368; called by muse, mutect2, varscan2
- PLPPR3 | c.1569C>T p.A523= (on ENST00000520876 / NM_001270366.2; = p.A551= on NM_024888.2) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs748405983, COSV100608894; called by muse, mutect2, varscan2
- PSMD6 | c.558T>G p.L186= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as COSV99896130; called by muse, mutect2, varscan2
- STAC3 | c.228G>A p.E76= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1185130762, COSV100234661; called by muse, mutect2, varscan2
- USH1G | c.474C>T p.H158= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs765860407, COSV100140562; called by muse, mutect2, varscan2
